Somatic mutation profile of tumor specimen TCGA-CG-4440-01A (aliquot TCGA-CG-4440-01A-01D-1158-08) from TCGA case TCGA-CG-4440, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.9 years (25,171 days).
Specimen TCGA-CG-4440-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb393b61-7d6f-4174-9f94-038c16c91335.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4440-10A (Blood Derived Normal), aliquot TCGA-CG-4440-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5314a36a-e684-4ed7-b64b-a5240994465a

The open-access MAF lists 140 somatic variants for this specimen: 113 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 25, Frame Shift Ins 3, Frame Shift Del 3, Intron 2, Nonsense Mutation 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRKCI | c.1438C>A p.R480S | Missense Mutation (SNP) | VAF 10/93 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen possibly damaging (0.874); catalogued as COSV55517137, COSV55517929; called by muse, mutect2, varscan2
- ADGRE3 | c.585A>C p.E195D | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as COSV53730003; called by muse, mutect2, varscan2
- ADGRL3 | c.1522A>T p.T508S (on ENST00000506720 / NM_001322402.2; = p.T440S on NM_015236.6) | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.071); catalogued as COSV72230260; called by muse, mutect2, varscan2
- AHCTF1 | c.4063G>A p.E1355K (on ENST00000366508; = p.E1329K on NM_015446.5) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV58248779; called by muse, mutect2, varscan2
- AHNAK | c.3263C>G p.S1088C | Missense Mutation (SNP) | VAF 114/409 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV57210923; called by muse, mutect2, varscan2
- AHNAK2 | c.16523C>G p.T5508R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs372998948, COSV60921403; called by muse, mutect2
- AHNAK2 | c.11727G>T p.K3909N | Missense Mutation (SNP) | VAF 167/560 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1240757649, COSV60910582, COSV60913250; called by muse, mutect2, varscan2
- ALDH4A1 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs764851299, COSV51891866; called by muse, mutect2, varscan2
- AQP10 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100270451; called by muse, varscan2
- ARID4A | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs774285006, COSV62163158; called by muse, mutect2, varscan2
- C22orf31 | c.10A>C p.I4L | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as COSV53310402; called by muse, mutect2, varscan2
- CASP2 | c.524A>G p.Q175R | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV60081831; called by muse, mutect2
- CDH26 | c.250T>C p.Y84H | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54845792; called by muse, mutect2, varscan2
- CENPU | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV55657194; called by muse, mutect2, varscan2
- CHRM1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs749521197, COSV61006574; called by muse, mutect2, varscan2
- CLSTN3 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs778011123, COSV56934798; called by muse, mutect2, varscan2
- COL5A1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV65667991; called by muse, mutect2, varscan2
- CRACD | c.3319C>T p.R1107W | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51719460; called by muse, mutect2, varscan2
- DNAJC21 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.281); catalogued as COSV57759975; called by muse, mutect2
- DPP6 | c.1107G>T p.E369D (on ENST00000377770 / NM_001364500.2; = p.E307D on NM_001936.5) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV59607901; called by muse, mutect2
- DPPA4 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.059); catalogued as COSV59510009; called by muse, mutect2, varscan2
- DSCAM | c.2405G>T p.G802V | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV68020931, COSV68025148; called by muse, mutect2, varscan2
- EPHB2 | c.2628T>G p.I876M (on ENST00000400191 / NM_001309193.2; = p.I877M on NM_004442.7) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65861839; called by muse, mutect2, varscan2
- EVI2B | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 62/424 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV58363816; called by muse, varscan2
- FBN1 | c.5409G>T p.L1803F | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs906226501, COSV57314566; called by muse, mutect2, varscan2
- FBN1 | c.3877A>C p.S1293R | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs761277748, COSV100356775, COSV57314574; called by muse, mutect2, varscan2
- FCRLA | c.175G>A p.E59K (on ENST00000367959; = p.E36K on NM_032738.4) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs779633030, COSV52685373; called by muse, mutect2, varscan2
- FIZ1 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1054064985, COSV55607560; called by muse, mutect2, varscan2
- FKBP14 | c.401T>G p.I134S | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV56107174; called by muse, mutect2, varscan2
- FMN2 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.244); catalogued as COSV60427033, COSV60437540; called by muse, mutect2
- FRAS1 | c.9316G>A p.G3106S | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1331714407, COSV53595990; called by muse, mutect2, varscan2
- FZD10 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV57473215; called by muse, mutect2, varscan2
- GC | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454524724, COSV56736835; called by muse, mutect2, varscan2
- GSK3B | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 103/363 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51773899; called by muse, mutect2, varscan2
- GTPBP4 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 26/116 reads (22%) | catalogued as COSV62550647; called by muse, mutect2
- HROB | c.944C>A p.P315H | Missense Mutation (SNP) | VAF 100/592 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV55369356; called by muse, mutect2, varscan2
- HSD3B1 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs370361626, COSV52490301; called by muse, mutect2, varscan2
- IFT122 | c.2825T>G p.F942C (on ENST00000348417 / NM_052989.3; = p.F883C on NM_018262.4) | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56202199; called by muse, mutect2, varscan2
- IGBP1P2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as rs372568409; called by muse, mutect2, varscan2
- IGFL4 | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV66618826; called by muse, mutect2, varscan2
- IRAK3 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99706403; called by muse, mutect2
- KCNA5 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs898525645, COSV52905174; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA5 | c.5551C>T p.R1851W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759686911, COSV53358044; called by muse, mutect2, varscan2
- LUZP2 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs150458536, COSV61201811; called by muse, mutect2, varscan2
- MCHR2 | c.623dup p.L210Sfs*23 | Frame Shift Ins (INS) | VAF 43/107 reads (40%) | catalogued as rs759525627; called by mutect2, varscan2
- NAV3 | c.5796A>C p.Q1932H (on ENST00000397909 / NM_001024383.2; = p.Q1910H on NM_014903.6) | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.465); catalogued as COSV57074738, COSV99896492; called by muse, mutect2, varscan2
- NCKAP5 | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.605); catalogued as COSV58439024; called by muse, mutect2, varscan2
- NF1 | c.1813A>T p.I605F | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.798); catalogued as COSV62200079; called by muse, mutect2, varscan2
- NLGN1 | c.2261T>A p.L754H | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100848798, COSV100850237, COSV64330434; called by muse, mutect2, varscan2
- NLRP8 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs201546502, COSV52586071; called by muse, mutect2, varscan2
- NOVA2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54356927; called by muse, mutect2
- NOX4 | c.20G>C p.S7T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV54451440; called by muse, mutect2, varscan2
- NPR1 | c.2552A>G p.Q851R | Missense Mutation (SNP) | VAF 50/456 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV64117499; called by muse, mutect2, varscan2
- NRG1 | c.1864G>T p.E622* (on ENST00000405005 / NM_013964.5; = p.E627* on NM_013956.5) | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as COSV55155671; called by muse, mutect2, varscan2
- OR51B4 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66516991, COSV66517465; called by muse, mutect2, varscan2
- OR52N4 | c.584A>C p.K195T | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.367); catalogued as COSV57890862; called by muse, mutect2
- OR5I1 | c.108G>T p.L36F | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV56886467; called by muse, mutect2, varscan2
- OR5I1 | c.106T>A p.L36M | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV56886478; called by muse, mutect2, varscan2
- OR6F1 | c.194A>C p.N65T | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs1037422030, COSV57467528; called by muse, mutect2, varscan2
- OR7G3 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV59640259; called by muse, mutect2, varscan2
- OXSR1 | c.59A>C p.Q20P | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.434); catalogued as COSV61258263; called by muse, mutect2, varscan2
- PARD3 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs141769427; called by muse, mutect2, varscan2
- PCDHB14 | c.286T>C p.C96R | Missense Mutation (SNP) | VAF 136/438 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53387931; called by muse, mutect2, varscan2
- PCDHGB3 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV53930957; called by muse, mutect2, varscan2
- PDE8A | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV59636428; called by muse, mutect2, varscan2
- PDIA5 | c.950A>G p.K317R | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV60248573; called by muse, mutect2, varscan2
- PDZRN4 | c.1799T>G p.L600R (on ENST00000402685 / NM_001164595.2; = p.L342R on NM_013377.4) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV54196850; called by muse, mutect2, varscan2
- PHF8 | c.1715G>C p.G572A (on ENST00000357988 / NM_001184896.1; = p.G536A on NM_015107.3) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.046); catalogued as COSV57680167, COSV57687645; called by muse, mutect2, varscan2
- PLEC | c.8866G>A p.V2956M (on ENST00000322810 / NM_201380.4; = p.V2846M on NM_000445.5) | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs782271365, COSV59626293; called by muse, mutect2, varscan2
- POLQ | c.1291G>C p.A431P | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV51749915, COSV51755801; called by muse, mutect2, varscan2
- PRB4 | c.736C>A p.P246T | Missense Mutation (SNP) | VAF 126/418 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV54396477; called by muse, mutect2, varscan2
- PTCD2 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as COSV100349014, COSV57337684; called by muse, mutect2, varscan2
- PTPRN | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55347226; called by muse, mutect2, varscan2
- PTPRZ1 | c.5504G>T p.R1835I | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66434974; called by muse, mutect2, varscan2
- QTRT2 | c.1171T>C p.F391L | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55559785; called by muse, mutect2, varscan2
- SART3 | c.2225C>G p.P742R (on ENST00000228284; = p.P724R on NM_014706.4) | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.273); catalogued as COSV57206770; called by muse, mutect2, varscan2
- SCN10A | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 171/298 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1553620983, COSV101479545, COSV71861011; called by muse, mutect2, varscan2
- SERPINA3 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs199923400, COSV67585905; called by muse, mutect2, varscan2
- SHISAL2A | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 112/736 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs752097440, COSV68979687; called by muse, varscan2
- SIPA1L1 | c.2978G>A p.R993H | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1243462975, COSV62169596; called by muse, mutect2, varscan2
- SLC4A10 | c.1310G>C p.R437P (on ENST00000446997 / NM_001354461.2; = p.R407P on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55770206, COSV55774465; called by muse, mutect2, varscan2
- SLCO1C1 | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV56869031, COSV99858593; called by muse, mutect2, varscan2
- SLFN11 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs369259962; called by muse, mutect2, varscan2
- SORBS1 | c.677G>A p.R226H (on ENST00000361941 / NM_001034954.2; = p.R194H on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as rs754084074, COSV53356222; called by muse, mutect2, varscan2
- SPNS2 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1342707656, COSV54596717; called by muse, varscan2
- SYN3 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs752060058, COSV100249870; called by muse, mutect2, varscan2
- SYNE1 | c.7787G>A p.R2596H (on ENST00000367255 / NM_182961.4; = p.R2603H on NM_033071.3) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs1252134300, COSV54914154; called by muse, mutect2, varscan2
- TDRD6 | c.1063A>G p.S355G | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV60175098; called by muse, varscan2
- TGM2 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs41274716, CM1111324, COSV63931102; called by muse, mutect2, varscan2
- THRAP3 | c.2269dup p.T757Nfs*6 | Frame Shift Ins (INS) | VAF 16/150 reads (11%) | catalogued as rs1443424346; called by mutect2, pindel
- TM6SF2 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV66985073; called by muse, mutect2, varscan2
- TNS3 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60789828; called by muse, mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 37/102 reads (36%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- TSHZ2 | c.2287C>A p.Q763K | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61588260; called by muse, mutect2, varscan2
- TSKU | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV60751359; called by muse, mutect2, varscan2
- TYR | c.799T>A p.S267T | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54473748; called by muse, mutect2, varscan2
- UBE4A | c.148T>G p.S50A | Missense Mutation (SNP) | VAF 62/489 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as COSV52803690; called by muse, mutect2, varscan2
- UGGT1 | c.2761A>C p.I921L | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52134835; called by muse, mutect2, varscan2
- UGT1A6 | c.994-1G>A p.X332_splice | Splice Site (SNP) | VAF 32/191 reads (17%) | catalogued as COSV59386972, COSV59390535; called by muse, mutect2, varscan2
- UMODL1 | c.3086G>A p.S1029N (on ENST00000408910 / NM_001004416.2; = p.S1157N on NM_173568.3) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs1430063321, COSV101252492, COSV101252677; called by muse, mutect2, varscan2
- USP30 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1413811231, COSV57448941; called by muse, mutect2, varscan2
- VPS13D | c.8484G>T p.K2828N | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV50633099; called by muse, mutect2, varscan2
- WDFY2 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 100/223 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.984); catalogued as rs140912157; called by muse, mutect2, varscan2
- WDR35 | c.2633C>T p.A878V (on ENST00000345530 / NM_001006657.2; = p.A867V on NM_020779.4) | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as COSV55602082; called by muse, mutect2, varscan2
- ZC3H13 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 102/235 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1370379931, COSV54451840; called by muse, varscan2
- ZNF417 | c.440T>A p.F147Y | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100364386; called by muse, mutect2, varscan2
- ZNF804B | c.122A>C p.K41T | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60824147; called by muse, mutect2, varscan2
- CCDC178 | c.2154dup p.D719Rfs*3 (on ENST00000383096 / NM_001105528.3; = p.D681Rfs*3 on NM_198995.3) | Frame Shift Ins (INS) | VAF 9/92 reads (10%) | called by mutect2, pindel
- FLG | c.63del p.D22Ifs*7 | Frame Shift Del (DEL) | VAF 20/199 reads (10%) | called by mutect2, pindel
- KBTBD6 | c.1319del p.L440Wfs*12 | Frame Shift Del (DEL) | VAF 82/205 reads (40%) | called by mutect2, varscan2
- KIR3DL2 | c.461T>G p.F154C | Missense Mutation (SNP) | VAF 89/676 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- OR8G2P | c.383G>T p.S128I | Missense Mutation (SNP) | VAF 130/432 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- PGR | c.2419_2421del p.E807del | In Frame Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- ACKR3 | c.339C>T p.G113= | Silent (SNP) | VAF 28/271 reads (10%) | catalogued as rs762709549, COSV56021329; called by muse, mutect2, varscan2
- ADARB2 | c.363G>A p.S121= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as rs1053706951, COSV67220909; called by muse, mutect2, varscan2
- ATP11C | c.738T>C p.N246= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV59562401; called by muse, mutect2, varscan2
- CCNA2 | c.864G>A p.K288= | Silent (SNP) | VAF 42/197 reads (21%) | catalogued as COSV52655302, COSV52655845; called by muse, mutect2, varscan2
- CEP97 | c.720G>A p.Q240= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV59124004, COSV59127324; called by muse, mutect2, varscan2
- CLEC4E | c.471T>A p.P157= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as COSV55225610; called by muse, mutect2
- DPPA5 | c.141C>T p.I47= | Silent (SNP) | VAF 60/140 reads (43%) | catalogued as COSV64875469; called by muse, mutect2, varscan2
- EVI2B | c.159G>A p.G53= | Silent (SNP) | VAF 55/472 reads (12%) | catalogued as COSV58363826; called by muse, varscan2
- FAM219A | c.438C>T p.D146= (on ENST00000445726; = p.D129= on NM_147202.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as rs747512027, COSV52620468; called by muse, mutect2, varscan2
- GCDH | c.441C>T p.L147= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs931207617, COSV55819721; called by muse, mutect2, varscan2
- IRAK3 | c.522A>T p.G174= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV99706406; called by muse, mutect2, varscan2
- KHDRBS3 | c.795T>G p.T265= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV63417120; called by muse, mutect2, varscan2
- KIAA1210 | c.1743T>C p.N581= | Silent (SNP) | VAF 67/135 reads (50%) | catalogued as COSV68176719; called by muse, mutect2, varscan2
- NFE2L1 | c.504C>T p.T168= | Silent (SNP) | VAF 60/188 reads (32%) | catalogued as rs1489373809, COSV62583072; called by muse, mutect2, varscan2
- OR2Z1 | c.462C>G p.L154= | Silent (SNP) | VAF 41/208 reads (20%) | catalogued as rs1555756767, COSV60692058; called by muse, mutect2, varscan2
- OR4K1 | c.783T>G p.P261= | Silent (SNP) | VAF 31/406 reads (8%) | catalogued as COSV53459790; called by muse, mutect2
- PRKAR1B | c.411C>G p.L137= | Silent (SNP) | VAF 78/284 reads (27%) | catalogued as rs768122368, COSV100816655, COSV64318376; called by muse, mutect2, varscan2
- PRPF40A | c.270C>A p.G90= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs755594619, COSV58442551; called by muse, mutect2, varscan2
- PTEN | c.99T>C p.I33= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as rs786201650, CD033225, COSV64294999; ClinVar: likely benign; called by muse, mutect2, varscan2
- SORL1 | c.2169G>A p.R723= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as rs1463688863, COSV52752817, COSV52756417; called by muse, varscan2
- SPATA31A3 | c.2094T>C p.S698= | Silent (SNP) | VAF 18/114 reads (16%) | called by mutect2, varscan2
- SPRY1 | c.291G>T p.L97= | Silent (SNP) | VAF 85/155 reads (55%) | catalogued as COSV59338311; called by muse, mutect2, varscan2
- USH1G | c.636C>T p.G212= | Silent (SNP) | VAF 88/155 reads (57%) | catalogued as COSV58881541; called by muse, mutect2, varscan2
- WAS | c.162C>T p.Y54= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as CM001388, COSV64996935; called by muse, mutect2, varscan2
- ZNF263 | c.804C>G p.T268= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV54596144; called by muse, mutect2, varscan2
- CCSER1 | c.2094+23147G>A | Intron (SNP) | VAF 32/302 reads (11%) | catalogued as rs200975463, COSV61419001; called by muse, varscan2
- METTL15 | c.779-2284T>G | Intron (SNP) | VAF 10/87 reads (11%) | catalogued as COSV100328686; called by muse, mutect2, varscan2
